Gene-level copy-number profile of tumor specimen TCGA-29-1711-01A from TCGA case TCGA-29-1711, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 45.1 years (16,485 days).
Specimen TCGA-29-1711-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.b51f1b66-75c2-4878-91b0-4293f81097ea.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1711-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6c9ac0b0-58e5-473e-8a89-d1d40d66c950

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 50; copy number 1: 16,927; copy number 2: 32,092; copy number 3: 8,904; copy number 4: 1,521; copy number 5: 23; copy number 6: 262; copy number 7: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-29-1711-01A-01D-0559-01): tumor purity 0.84, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 50 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:59,171,183–59,212,788, 3 genes: MIR2116, LDHAL6B, RNU4-80P.
- chr21:14,485,228–15,880,069, 25 genes (within-gene range 0–1): SAMSN1, SAMSN1-AS1, AF127936.1, POLR2CP1, GAPDHP16, AF127577.4, LINC02246, RBMX2P1, AF127577.3, NRIP1, AF127577.1, AF127577.2, AF127577.6, AF127577.5, AF222684.1, AF222685.1, AF130248.1, AF246928.1, AJ009632.2, CYCSP42, AJ009632.1, RNU6-1326P, RAD23BP3, USP25, RBPMSLP.
- chr21:16,035,413–16,121,644, 3 genes: RNU6-426P, VDAC2P1, RPS26P5.
- chr21:20,651,450–21,615,437, 5 genes (within-gene range 0–2): LINC00320, PPIAP1, NCAM2, AP001136.1, AP001117.1.
- chr21:24,840,550–25,518,865, 14 genes: LINC01692, AP000402.1, AP000146.1, AP001342.1, AP000235.1, AP000233.2, RN7SKP236, AP000233.1, AP001341.1, RNA5SP489, RPL13AP7, AP001340.1, LINC00158, AP000221.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 320 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:153,001,747–153,205,120, 13 genes, copy number 6: SPRR3, AL356867.2, AL356867.1, SPRR1B, SPRR2D, SPRR2A, SPRR2B, SPRR2E, SPRR2F, SPRR2C, SPRR2G, AL161636.1, LELP1.
- chr2:54,029,552–54,051,760, 2 genes, copy number 6: RPL21P30, HMGB1P31.
- chr2:121,649,320–123,869,570, 18 genes, copy number 5: NIFK-AS1, RPL12P15, AC018737.2, NPM1P32, NIFK, TSN, AC018737.1, LINC01823, AC011246.1, AC073632.1, AC062020.1, LINC01826, AC073409.2, AC073409.1, ELOAP1, PSMD14P1, AC064859.1, RN7SKP102.
- chr6:1,312,098–1,395,603, 5 genes, copy number 5: FOXQ1, LINC01394, AL034346.1, FOXF2, MIR6720.
- chr20:47,656,348–48,275,392, 16 genes, copy number 6 (within-gene range 4–6): SULF2, AL354813.1, RNU7-173P, SRMP1, RNA5SP486, RNU7-92P, AL357558.2, AL357558.1, AL357558.3, LINC01522, LINC01523, AL139351.2, AL139351.3, AL139351.1, AL136102.1, AL121888.2.
- chr20:55,997,357–64,313,132, 258 genes, copy number 6–7 (within-gene range 3–7) (broad region; genes not listed).
- chr22:16,961,936–17,115,694, 8 genes, copy number 6 (within-gene range 3–6): GAB4, AC006548.2, VN1R9P, CECR7, AC006946.2, AC006946.3, IL17RA, AC006946.1.

Autosomal genes at a single copy (total copy number 1): 16,927. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
